Somatic mutation profile of tumor specimen TARGET-20-PASYVX-09A (aliquot TARGET-20-PASYVX-09A-01D) from TARGET case TARGET-20-PASYVX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.3 years (3,771 days).
Specimen TARGET-20-PASYVX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a786ada7-1c21-4ac6-9eca-9d407d3b89e5.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASYVX-14A (Bone Marrow Normal), aliquot TARGET-20-PASYVX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85ee85d7-1f7e-41e3-8c99-4c66823023f5

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2516A>G p.D839G | Missense Mutation (SNP) | VAF 92/250 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs991132188, COSV54045448; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SRCAP | c.977delinsCCCC p.R326delinsPP | In Frame Ins (INS) | VAF 58/142 reads (41%) | catalogued as COSV52666823, COSV99351497; called by pindel, varscan2*
